Somatic mutation profile of tumor specimen HCM-WCMC-0753-C54-01A (aliquot HCM-WCMC-0753-C54-01A-01D-A87L-36) from HCMI case HCM-WCMC-0753-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 53.2 years (19,444 days).
Specimen HCM-WCMC-0753-C54-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a9f9fff-e6d3-4098-b478-8ed3117be61d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0753-C54-10A (Blood Derived Normal), aliquot HCM-WCMC-0753-C54-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfa7e515-e8fb-4fb2-ac97-36bbd6436487

The open-access MAF lists 49 somatic variants for this specimen: 41 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 5, Frame Shift Ins 2, Frame Shift Del 2, 5'UTR 1, Splice Site 1, 3'UTR 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 124/624 reads (20%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 223/1082 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGMO | c.174C>A p.S58R | Missense Mutation (SNP) | VAF 35/860 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1414183977; called by muse, mutect2
- AP002512.3 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 139/667 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs142650803; called by muse, mutect2, varscan2
- BOLL | c.352+1G>A p.X118_splice | Splice Site (SNP) | VAF 72/473 reads (15%) | catalogued as COSV56573067; called by muse, mutect2, varscan2
- CASP10 | c.1237G>A p.E413K (on ENST00000272879 / NM_032974.5; = p.E370K on NM_001230.5) | Missense Mutation (SNP) | VAF 145/728 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780430275, COSV53777308; called by muse, mutect2, varscan2
- CBFA2T3 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 170/741 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs750224332; called by muse, mutect2, varscan2
- CDC42BPB | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 180/788 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs138666514, COSV63473797; called by muse, mutect2, varscan2
- CTNNA1 | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 143/867 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as rs992791147; called by muse, mutect2, varscan2
- MAP3K2 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 85/643 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs748193402, COSV61294473; called by muse, mutect2, varscan2
- MYO3A | c.1990C>T p.R664* | Nonsense Mutation (SNP) | VAF 113/598 reads (19%) | catalogued as COSV56323615; called by muse, mutect2, varscan2
- NCEH1 | c.502G>T p.D168Y (on ENST00000538775; = p.D128Y on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/604 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.436); catalogued as COSV56437107; called by muse, mutect2, varscan2
- NRP2 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 162/891 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.17); catalogued as rs757566894; called by muse, mutect2, varscan2
- PCDH15 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 102/449 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.191); catalogued as rs757431276; called by muse, mutect2, varscan2
- PELP1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 131/680 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs778536878, COSV52592761; called by muse, mutect2, varscan2
- POR | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 123/578 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67516263; called by muse, mutect2, varscan2
- PPTC7 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 146/907 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as rs200469790; called by muse, mutect2, varscan2
- PRAMEF14 | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 119/704 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs771089877; called by muse, mutect2, varscan2
- PROCA1 | c.809C>T p.P270L (on ENST00000439862 / NM_001366301.1; = p.P242L on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 173/808 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as rs747596303; called by muse, mutect2, varscan2
- PRSS38 | c.302G>C p.C101S | Missense Mutation (SNP) | VAF 74/348 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64541184; called by muse, mutect2, varscan2
- SI | c.3232C>T p.R1078W | Missense Mutation (SNP) | VAF 96/520 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769259229, COSV52270933, COSV52283854; called by muse, varscan2
- SKIV2L | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 150/934 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs547774154; called by muse, mutect2, varscan2
- SLC4A2 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 132/568 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs201086697, COSV59657692; called by muse, mutect2, varscan2
- SULT6B1 | c.199G>A p.G67S (on ENST00000535679 / NM_001367551.1; = p.G29S on NM_001032377.2) | Missense Mutation (SNP) | VAF 101/619 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs761217393; called by muse, mutect2, varscan2
- TAS2R39 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 118/658 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs749967220, COSV71470883; called by muse, mutect2, varscan2
- WDR87 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 105/480 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372178192; called by muse, mutect2, varscan2
- ZC3H18 | c.2128G>A p.V710I | Missense Mutation (SNP) | VAF 90/436 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.991); catalogued as rs370561351; called by muse, mutect2, varscan2
- ZNF316 | c.2936C>T p.A979V | Missense Mutation (SNP) | VAF 110/418 reads (26%) | SIFT deleterious, low confidence (0.01); catalogued as rs1251424280; called by muse, varscan2
- ABCA7 | c.3250C>A p.H1084N | Missense Mutation (SNP) | VAF 84/410 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ANKS6 | c.1818C>A p.D606E | Missense Mutation (SNP) | VAF 122/564 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.754); called by muse, mutect2
- CDON | c.2572C>A p.P858T | Missense Mutation (SNP) | VAF 62/539 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM83B | c.809A>G p.D270G | Missense Mutation (SNP) | VAF 128/555 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLRT1 | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 143/662 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PGAP4 | c.632A>C p.E211A | Missense Mutation (SNP) | VAF 184/982 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTEN | c.898dup p.I300Nfs*3 | Frame Shift Ins (INS) | VAF 180/610 reads (30%) | called by mutect2, varscan2
- PTPN14 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 200/975 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPRQ | c.5125C>G p.P1709A (on ENST00000616559; = p.P1667A on NM_001145026.2) | Missense Mutation (SNP) | VAF 84/522 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- S100A14 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 120/753 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SHROOM3 | c.4004C>T p.P1335L | Missense Mutation (SNP) | VAF 181/842 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIAL1 | c.342del p.K114Nfs*15 | Frame Shift Del (DEL) | VAF 224/581 reads (39%) | called by mutect2, varscan2
- ZNF226 | c.153del p.F52Sfs*8 | Frame Shift Del (DEL) | VAF 78/443 reads (18%) | called by mutect2, varscan2
- CSPP1 | c.24C>G p.A8= | Silent (SNP) | VAF 95/564 reads (17%) | catalogued as rs988655476, COSV51583853; called by muse, mutect2, varscan2
- FAT1 | c.2574G>A p.T858= | Silent (SNP) | VAF 152/823 reads (18%) | catalogued as rs376884651; called by muse, mutect2, varscan2
- HEPH | c.3363C>T p.L1121= (on ENST00000343002; = p.L854= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 151/999 reads (15%) | catalogued as rs766265686, COSV57963845; called by muse, mutect2, varscan2
- HTR5A | c.189G>A p.A63= | Silent (SNP) | VAF 129/722 reads (18%) | catalogued as rs1563417742, COSV55284856; called by muse, mutect2, varscan2
- UNC13A | c.5064G>A p.K1688= | Silent (SNP) | VAF 143/553 reads (26%) | catalogued as rs753658542; called by muse, mutect2, varscan2
- B4GALT2 | c.-21G>A | 5'UTR (SNP) | VAF 119/699 reads (17%) | catalogued as rs375329179; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+26794T>A | Intron (SNP) | VAF 88/466 reads (19%) | called by muse, mutect2, varscan2
- ZNF662 | c.*2250T>G | 3'UTR (SNP) | VAF 23/520 reads (4%) | called by muse, mutect2
